Gene-level copy-number profile of tumor specimen C3L-01295-54 from CPTAC case C3L-01295, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.9 years (25,914 days).
Specimen C3L-01295-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file afe07321-6f63-4788-bc9f-55fc9129c16c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01295-51 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,665 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/27330266-4498-4be0-9e87-2621eb5d3ce1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 486; copy number 1: 8,512; copy number 2: 13,854; copy number 3: 14,811; copy number 4: 8,271; copy number 5: 2,928; copy number 6: 2,198; copy number 7: 1,298; copy number 8: 1,140; copy number 9: 607; copy number 10: 492; copy number 11: 270; copy number 12: 374; copy number 13: 159; copy number 14: 238; copy number 15: 95; copy number 16: 93; copy number 17: 63; copy number 18: 68; copy number 19: 78; copy number 20: 106; copy number 21: 90; copy number 22: 29; copy number 23: 56; copy number 24: 39; copy number 25: 35; copy number 26: 25; copy number 27: 52; copy number 28: 32; copy number 29: 79; copy number 30: 78; copy number 31: 66; copy number 32: 24; copy number 33: 15; copy number 34: 39; copy number 35: 25; copy number 36: 11; copy number 37: 4; copy number 38: 12; copy number 39: 21; copy number 40: 24; copy number 41: 20; copy number 42: 18; copy number 43: 10; copy number 44: 29; copy number 45: 7; copy number 46: 39; copy number 47: 22; copy number 48: 11; copy number 49: 26; copy number 50: 10; copy number 51: 18; copy number 52: 6; copy number 53: 11; copy number 54: 12; copy number 55: 9; copy number 56: 5; copy number 57: 12; copy number 58: 9; copy number 59: 7; copy number 60: 11; copy number 61: 10; copy number 62: 7; copy number 63: 10; copy number 64: 9; copy number 65: 6; copy number 66: 7; copy number 67: 6; copy number 68: 7; copy number 69: 6; copy number 70: 5; copy number 71: 9; copy number 72: 40; copy number 73: 7; copy number 74: 6; copy number 75: 11; copy number 76: 10; copy number 77: 7; copy number 78: 7; copy number 79: 8; copy number 80: 6; copy number 81: 3; copy number 82: 7; copy number 83: 8; copy number 84: 3; copy number 85: 4; copy number 86: 4; copy number 87: 3; copy number 88: 7; copy number 89: 6; copy number 90: 8; copy number 91: 4; copy number 92: 5; copy number 93: 13; copy number 94: 2; copy number 95: 9; copy number 96: 8; copy number 97: 19; copy number 98: 6; copy number 99: 6; copy number 100: 4; copy number 101: 7; copy number 102: 1; copy number 103: 2; copy number 104: 3; copy number 105: 11; copy number 106: 6; copy number 107: 3; copy number 108: 3; copy number 109: 3; copy number 110: 2; copy number 111: 5; copy number 112: 1; copy number 113: 4; copy number 114: 2; copy number 115: 2; copy number 116: 10; copy number 117: 4; copy number 118: 5; copy number 120: 8; copy number 121: 1; copy number 122: 4; copy number 123: 3; copy number 124: 8; copy number 125: 1; copy number 126: 2; copy number 127: 6; copy number 129: 3; copy number 130: 1; copy number 131: 1; copy number 132: 2; copy number 134: 3; copy number 137: 4; copy number 138: 5; copy number 139: 1; copy number 140: 9; copy number 141: 30; copy number 142: 2; copy number 143: 4; copy number 145: 2; copy number 146: 2; copy number 147: 2; copy number 151: 3; copy number 152: 1; copy number 153: 1; copy number 154: 3; copy number 155: 3; copy number 156: 4; copy number 157: 3; copy number 158: 4; copy number 159: 4; copy number 160: 2; copy number 161: 2; copy number 162: 2; copy number 164: 2; copy number 165: 1; copy number 166: 7; copy number 167: 3; copy number 169: 2; copy number 170: 2; copy number 171: 4; copy number 172: 2; copy number 173: 7; copy number 175: 4; copy number 178: 2; copy number 179: 1; copy number 182: 1; copy number 183: 3; copy number 184: 1; copy number 185: 2; copy number 187: 1; copy number 189: 2; copy number 190: 13; copy number 191: 4; copy number 192: 1; copy number 193: 2; copy number 194: 1; copy number 195: 1; copy number 196: 1; copy number 197: 3; copy number 198: 3; copy number 200: 1; copy number 201: 6; copy number 202: 1; copy number 204: 1; copy number 205: 2; copy number 206: 1; copy number 209: 4; copy number 210: 1; copy number 212: 1; copy number 213: 1; copy number 214: 2; copy number 217: 7; copy number 220: 3; copy number 223: 1; copy number 226: 1; copy number 227: 2; copy number 229: 2; copy number 233: 1; copy number 235: 4; copy number 236: 3; copy number 237: 1; copy number 239: 1; copy number 240: 2; copy number 241: 1; copy number 244: 2; copy number 246: 1; copy number 249: 1; copy number 250: 2; copy number 251: 1; copy number 253: 2; copy number 261: 3; copy number 262: 3; copy number 264: 10; copy number 265: 1; copy number 266: 1; copy number 270: 2; copy number 272: 1; copy number 276: 1; copy number 277: 1; copy number 281: 4; copy number 283: 1; copy number 284: 1; copy number 286: 1; copy number 292: 1; copy number 293: 3; copy number 296: 1; copy number 300: 1; copy number 301: 2; copy number 302: 2; copy number 305: 1; copy number 314: 1; copy number 315: 2; copy number 317: 1; copy number 320: 1; copy number 322: 1; copy number 328: 2; copy number 331: 1; copy number 333: 1; copy number 335: 1; copy number 338: 1; copy number 341: 4; copy number 350: 1; copy number 357: 3; copy number 358: 2; copy number 361: 1; copy number 363: 2; copy number 367: 2; copy number 371: 1; copy number 376: 1; copy number 380: 1; copy number 385: 2; copy number 425: 1; copy number 439: 3; copy number 441: 1; copy number 445: 1; copy number 446: 1; copy number 473: 1; copy number 501: 2; copy number 521: 4; copy number 528: 1; copy number 529: 1; copy number 539: 1; copy number 572: 1; copy number 598: 2; copy number 601: 7; copy number 654: 2; copy number 680: 1; copy number 720: 2; copy number 744: 3; copy number 957: 1; copy number 2149: 2.

Homozygous deletions (total copy number 0; autosomes only): 454 genes in 283 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–944,581, 5 genes (within-gene range 0–8): AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11.
- chr1:1,891,471–1,917,296, 2 genes: AL109917.1, CALML6.
- chr1:3,132,927–3,208,664, 2 genes (within-gene range 0–1): AL008733.1, AL512383.1.
- chr1:22,633,258–22,648,110, 3 genes: MIR6127, C1QA, C1QC.
- chr1:22,835,713–22,965,338, 3 genes (within-gene range 0–1): AL512444.1, MIR4253, LACTBL1.
- chr1:110,936,369–110,952,848, 2 genes (within-gene range 0–7): AL360270.2, AL360270.1.
- chr1:120,942,600–121,116,676, 8 genes (within-gene range 0–2): RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2.
- chr1:166,022,215–166,042,350, 2 genes: RPS3AP10, RNA5SP64.
- chr3:12,877,522–13,283,281, 3 genes (within-gene range 0–29): LINC02022, IQSEC1, AC069271.1.
- chr5:139,644,460–139,683,882, 3 genes: AC113361.1, CXXC5, CXXC5-AS1.
- chr5:176,143,078–176,203,710, 5 genes: AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1.
- chr7:484,107–525,238, 3 genes: AC147651.1, PDGFA, HRAT92.
- chr7:102,637,025–102,671,641, 4 genes (within-gene range 0–13): UPK3BL1, AC105052.3, SPDYE2B, POLR2J2.
- chr7:129,774,692–129,785,185, 3 genes: MIR96, MIR183, AC084864.1.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr8:134,792,020–134,842,637, 5 genes: AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250.
- chr9:129,430,652–129,513,687, 5 genes (within-gene range 0–1): AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2.
- chr10:69,575,807–69,596,436, 6 genes: AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20.
- chr11:1,274,371–1,462,689, 3 genes: TOLLIP, TOLLIP-AS1, BRSK2.
- chr11:1,991,096–2,001,470, 5 genes: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:64,881,535–64,893,449, 4 genes (within-gene range 0–48): AP001187.1, MIR194-2HG, MIR192, MIR194-2.
- chr11:67,362,414–67,374,932, 3 genes (within-gene range 0–1): RN7SKP239, CLCF1, AP003419.3.
- chr12:34,190,471–34,219,246, 3 genes (within-gene range 0–2): AC140847.2, RNA5SP357, DUX4L27.
- chr12:38,155,476–38,167,631, 3 genes: AC079460.2, RNA5SP358, RNA5SP359.
- chr12:131,620,178–131,661,823, 4 genes (within-gene range 0–1): AC117500.5, AC117500.3, LINC02414, AC117500.4.
- chr12:132,489,551–132,585,188, 4 genes (within-gene range 0–6): FBRSL1, AC131212.3, AC131212.2, MIR6763.
- chr12:132,918,306–133,107,544, 10 genes (within-gene range 0–8): ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140.
- chr13:112,964,835–113,120,685, 5 genes (within-gene range 0–1): AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7.
- chr15:75,674,322–75,712,848, 3 genes (within-gene range 0–1): CSPG4, AC105020.4, AC105020.1.
- chr16:35,221,583–35,259,629, 5 genes (within-gene range 0–1): RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8.
- chr17:17,504,005–17,610,485, 5 genes (within-gene range 0–23): AC020558.6, PEMT, AC020558.2, RNU6-468P, AC020558.1.
- chr17:81,362,272–81,390,319, 4 genes: AC110285.3, AC110285.1, AC110285.5, AC110285.2.
- chr17:81,918,270–81,930,753, 3 genes (within-gene range 0–9): MAFG, AC145207.8, MAFG-DT.
- chr18:14,946,267–14,979,839, 3 genes: LINC01443, LINC01444, AP005121.2.
- chr19:40,443,436–40,465,764, 3 genes (within-gene range 0–1): AC010271.1, BLVRB, Metazoa_SRP.
- chr20:33,657,087–33,686,385, 6 genes (within-gene range 0–55): NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1.
- chr21:44,989,864–45,004,727, 3 genes: LINC00163, LINC00165, PICSAR.
- chr22:32,121,977–32,143,272, 4 genes: AP1B1P1, Z83839.1, AP1B1P2, Z83839.2.
- chr22:45,875,932–46,057,210, 9 genes (within-gene range 0–1): BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1.
- chr22:48,489,553–48,850,912, 3 genes (within-gene range 0–1): TAFA5, Z84468.1, MIR4535.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,535 genes in 1,437 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,947,190–111,768,000, 37 genes, copy number 7–11 (within-gene range 0–11): LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1, AL355816.1, AL355816.2, DENND2D, CHI3L2, CHIAP1, CHIAP2, CHIA, AL356387.1, AL356387.2, PIFO, CHIAP3, PGBP, OVGP1, AL390195.2, UBE2FP3, AL390195.1, WDR77, Y_RNA, ATP5PB, C1orf162, TMIGD3, RNU6-792P, ADORA3, RAP1A, LINC01160, KRT18P57, RNU6-151P, INKA2, INKA2-AS1, AL049557.1, DDX20.
- chr1:143,419,625–147,517,875, 133 genes, copy number 7–46 (broad region; genes not listed).
- chr1:147,840,962–149,747,818, 70 genes, copy number 9–16 (within-gene range 2–16) (broad region; genes not listed).
- chr1:152,168,125–152,885,047, 33 genes, copy number 8–19 (within-gene range 1–19): FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN, LCE5A, CRCT1, LCE3E, LCE3D, LCE3C, LCE3B, LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, SMCP.
- chr1:158,327,951–158,883,500, 29 genes, copy number 8–34: CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P.
- chr1:182,378,098–183,245,127, 25 genes, copy number 7–75: GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2.
- chr1:247,416,156–248,645,278, 71 genes, copy number 7–680 (within-gene range 4–680) (broad region; genes not listed).
- chr2:74,211,604–74,893,359, 42 genes, copy number 7 (within-gene range 1–7): AC006030.1, SLC4A5, KRT18P26, RNU6-542P, NECAP1P2, TAF13P2, DCTN1, DCTN1-AS1, AC005041.1, AC005041.2, C2orf81, AC005041.4, HMGA1P8, WDR54, RTKN, INO80B, INO80B-WBP1, WBP1, MOGS, AC005041.5, MRPL53, CCDC142, TTC31, LBX2, AC005041.3, LBX2-AS1, PCGF1, TLX2, DQX1, AUP1, HTRA2, LOXL3, DOK1, M1AP, TOR1BP1, TVP23BP2, SEMA4F, AC007387.2, RPS28P5, AC007387.1, AC019069.1, HK2.
- chr2:88,446,787–89,085,787, 30 genes, copy number 8–31 (within-gene range 1–1708): FOXI3, TEX37, AC104134.1, EIF2AK3, EIF2AK3-DT, RPIA, ANKRD36BP2, MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV3-7, IGKV1-8, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:89,128,724–95,053,992, 110 genes, copy number 7–744 (within-gene range 0–744) (broad region; genes not listed).
- chr5:69,560,191–71,446,772, 35 genes, copy number 9–82: GTF2H2C, NAIPP3, AC139495.2, GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4, GUSBP9, GUSBP17, LINC02197, AC145141.2, PMCHL2, AC145141.1.
- chr5:140,647,058–141,012,347, 34 genes, copy number 7–28 (within-gene range 4–28): IK, MIR3655, WDR55, DND1, HARS1, HARS2, ZMAT2, VTRNA1-1, VTRNA1-2, VTRNA1-3, AC116353.4, AC116353.3, AC005609.5, PCDHA1, PCDHA2, PCDHA3, PCDHA4, PCDHA5, PCDHA6, PCDHA7, PCDHA8, PCDHA9, AC005609.2, PCDHA10, PCDHA14, AC005609.4, PCDHA11, PCDHA12, AC005609.3, AC005609.1, PCDHA13, PCDHAC1, AC010223.1, PCDHAC2.
- chr5:141,100,242–141,682,230, 66 genes, copy number 8–72 (broad region; genes not listed).
- chr6:25,962,802–26,687,964, 63 genes, copy number 7–8 (broad region; genes not listed).
- chr6:29,425,504–30,364,280, 87 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:31,479,973–33,457,544, 183 genes, copy number 8–12 (broad region; genes not listed).
- chr7:141,652,381–143,391,111, 138 genes, copy number 8–17 (within-gene range 1–17) (broad region; genes not listed).
- chr11:4,449,295–5,200,682, 54 genes, copy number 8–10: OR52K2, OR52K1, OR52M2P, OR52M1, C11orf40, OR52I2, OR52I1, TRIM68, OR51D1, OR51E1, OR51A9P, OR51E2, OR51C1P, MMP26, OR51F5P, OR51C4P, KRT8P49, OR51F3P, OR51F4P, SNORA62, OR51F1, OR51N1P, OR52Y1P, OR52R1, OR51F2, OR51A8P, OR51S1, OR51H1, OR51H2P, OR51T1, OR51A6P, OR51A7, OR51G2, OR51G1, OR51A3P, OR51A4, OR51A2, OR51A5P, OR51L1, OR51P1P, OR52J2P, OR52J3, OR52E2, OR52E1, OR52S1P, OR52E3P, OR52J1P, AC113331.1, OR52A4P, OR52A5, OR52A1, OR51A1P, OR52Z1, OR51V1.
- chr11:5,225,464–5,678,434, 26 genes, copy number 21–49 (within-gene range 5–49): HBB, HBD, HBBP1, BGLT3, HBG1, AC104389.6, HBG2, AC104389.5, HBE1, OR51AB1P, OR51B4, OR51B5, OR51B3P, OR51B2, OR51B8P, OR51B6, AC104389.3, AC104389.4, OR51M1, OR51J1, OR51Q1, OR51K1P, OR51I1, OR51I2, OR51A10P, OR52D1.
- chr11:5,514,393–7,234,837, 94 genes, copy number 8–27 (broad region; genes not listed).
- chr11:48,216,810–49,379,669, 42 genes, copy number 9–60: OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1.
- chr11:55,554,307–56,703,884, 90 genes, copy number 10–266 (broad region; genes not listed).
- chr11:89,177,875–90,126,061, 55 genes, copy number 8–281: TYR, CBX3P7, AP000720.1, AP000720.2, NOX4, H3P34, AP003400.4, AP003400.5, AP003400.1, AP003400.2, AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.1, AP000648.3.
- chr11:118,994,824–119,526,664, 40 genes, copy number 7–165: CENATAC-DT, CENATAC, RPL23AP64, AP003392.1, AP003392.2, RPS25, TRAPPC4, AP003392.15, SLC37A4, AP003392.3, HYOU1, AP003392.4, AP003392.5, VPS11, HMBS, H2AX, DPAGT1, C2CD2L, HINFP, ABCG4, NLRX1, PDZD3, CCDC153, CBL, RNU6-262P, MCAM, MIR6756, AP002956.1, RNF26, AP003396.1, C1QTNF5, MFRP, USP2, USP2-AS1, AP003396.3, AP003396.2, AP003396.4, THY1, THY1-AS1, DUXAP5.
- chr11:123,723,914–124,766,119, 58 genes, copy number 9–371: ZNF202, OR6X1, RNU1-21P, OR6M1, OR6M2P, OR6M3P, TMEM225, OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1, OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2, OR8B3, OR8X1P, OR8B4, OR8B8, OR8A2P, OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, VSIG2, ESAM, AP000866.2.
- chr12:6,438,498–10,130,258, 217 genes, copy number 7–8 (broad region; genes not listed).
- chr12:52,164,115–53,079,404, 60 genes, copy number 8–13: LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3.
- chr12:55,900,300–56,382,711, 46 genes, copy number 7: GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1.
- chr14:18,333,726–20,641,691, 132 genes, copy number 8–68 (broad region; genes not listed).
- chr14:21,633,836–22,552,156, 137 genes, copy number 7–24 (broad region; genes not listed).
- chr14:106,174,342–106,879,812, 108 genes, copy number 8–35 (within-gene range 6–568) (broad region; genes not listed).
- chr15:28,111,040–28,738,384, 27 genes, copy number 7–9 (within-gene range 1–42): HERC2, RPL41P2, HERC2P1, AC091304.4, AC091304.1, AC091304.3, GOLGA8F, RN7SL238P, ABCB10P3, AC091304.8, AC091304.5, MIR4509-2, AC091304.2, AC138749.4, MIR4509-3, AC138749.7, ABCB10P4, GOLGA8G, Metazoa_SRP, AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2, GOLGA8M, RN7SL719P.
- chr15:43,267,904–43,868,412, 35 genes, copy number 7: ATP5PDP1, TGM7, AC009852.1, LCMT2, ADAL, ZSCAN29, TUBGCP4, RN7SL487P, TP53BP1, MAP1A, PPIP5K1, CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1, CKMT1A, STRCP1, RNU6-353P, CATSPER2P1, RNU6-354P, PDIA3, ELL3, AC018512.1, SERF2, MIR1282, SERINC4, HYPK, MFAP1, WDR76, Y_RNA.
- chr17:7,549,058–8,057,621, 41 genes, copy number 12–35: TNFSF12, TNFSF12-TNFSF13, AC016876.3, TNFSF13, SENP3, SENP3-EIF4A1, EIF4A1, AC016876.2, SNORA48, SNORD10, SNORA67, CD68, AC016876.1, MPDU1, SOX15, FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4, CHD3, SCARNA21, RNF227, KCNAB3, AC104581.2, TRAPPC1, CNTROB, AC104581.1, GUCY2D, AC104581.3, ALOX15B, AC129492.2.
- chr17:41,040,541–41,492,546, 49 genes, copy number 11–29: KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36.
- chr17:75,751,594–76,240,493, 30 genes, copy number 8 (within-gene range 3–8): GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1, RNF157, ATP5MGP6.
- chr19:54,617,158–55,123,292, 37 genes, copy number 10: LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1, LILRP1, AC245128.2, LILRP2, KIR3DL3, AC245128.1, KIR2DL3, KIR2DP1, KIR2DL1, KIR3DP1, KIR2DL4, KIR3DL1, KIR2DS4, KIR3DL2, RNU6-222P, FCAR, AC245128.3, NCR1, NLRP7, AC011476.8, NLRP2, AC011476.1, AC011476.3, GP6, AC011476.2, RDH13, EPS8L1, PPP1R12C, AC010327.8, AC010327.3, MIR7975.
- chr21:7,744,962–13,120,807, 74 genes, copy number 8–2149 (broad region; genes not listed).
- chr21:30,263,380–30,762,882, 39 genes, copy number 9–173: RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P, KRTAP19-6, KRTAP19-7, KRTAP22-2, KRTAP6-3, KRTAP6-2, KRTAP22-1, KRTAP6-1, KRTAP20-1, KRTAP20-4, KRTAP20-2, KRTAP20-3, KRTAP21-3, KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1.
- chr22:22,692,778–22,896,111, 34 genes, copy number 8–9 (within-gene range 3–9): AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5.

Autosomal genes at a single copy (total copy number 1): 7,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
